Somatic mutation profile of tumor specimen TCGA-BQ-7062-01A (aliquot TCGA-BQ-7062-01A-11D-1961-08) from TCGA case TCGA-BQ-7062, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 64.5 years (23,559 days).
Specimen TCGA-BQ-7062-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e513fb2d-fbbf-43a0-9be8-7b3a03ed1bcf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-7062-11A (Solid Tissue Normal), aliquot TCGA-BQ-7062-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80fef4ec-1e0f-40d8-9ac5-d27aa63c4c8c

The open-access MAF lists 41 somatic variants for this specimen: 34 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 28, Silent 7, Frame Shift Del 3, In Frame Del 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADA | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65740099; called by muse, mutect2, varscan2
- ALPI | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs1207659360, COSV55014622; called by muse, varscan2
- CHRNA5 | c.1374A>C p.L458F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV55138667; called by muse, mutect2, varscan2
- DGKE | c.1043A>G p.D348G | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs777877548, COSV52349823; called by muse, mutect2, varscan2
- DMBT1 | c.2402G>A p.R801H | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs757332645, COSV57539304, COSV57549821; called by muse, mutect2
- HCAR2 | c.436A>T p.I146F | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.027); catalogued as COSV61024901; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 24/92 reads (26%) | catalogued as COSV57132311; called by muse, mutect2, varscan2
- HRG | c.137A>T p.Y46F | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.624); catalogued as COSV51645739; called by muse, mutect2, varscan2
- LMBR1L | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 129/287 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.273); catalogued as COSV57267712; called by muse, mutect2, varscan2
- MICALL1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV53240769; called by muse, mutect2, varscan2
- MORC4 | c.1325T>C p.I442T | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as rs764227066, COSV55242330; called by muse, mutect2, varscan2
- NADK | c.631T>A p.F211I | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58272319; called by muse, mutect2, varscan2
- NDUFAF3 | c.176A>T p.Y59F | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1430874359, COSV58245037; called by muse, mutect2, varscan2
- NFASC | c.416C>A p.S139Y (on ENST00000339876 / NM_001378329.1; = p.S133Y on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100364460; called by muse, mutect2, varscan2
- PAH | c.1235T>C p.V412A | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as CM1314655, COSV61016549; called by muse, mutect2, varscan2
- PSCA | c.127C>G p.R43G | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.633); catalogued as COSV100008257, COSV56652700; called by muse, mutect2, varscan2
- RAD51AP1 | c.456A>T p.L152F (on ENST00000228843 / NM_001130862.2; = p.L135F on NM_006479.5) | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.171); catalogued as COSV57409970; called by muse, mutect2, varscan2
- RNF167 | c.1019T>C p.L340P | Missense Mutation (SNP) | VAF 90/400 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1395935097, COSV52591013; called by muse, mutect2, varscan2
- RPL11 | c.316T>G p.F106V (on ENST00000374550 / NM_001199802.1; = p.F107V on NM_000975.5) | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV65778693; called by muse, mutect2, varscan2
- S100A7L2 | c.299G>T p.S100I | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV64195167; called by muse, varscan2
- SCAP | c.3662G>T p.C1221F | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV55544675; called by muse, mutect2, varscan2
- TERF1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.686); catalogued as rs370999354; called by muse, mutect2, varscan2
- TLN1 | c.7372G>C p.A2458P | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); catalogued as COSV59207503; called by muse, mutect2, varscan2
- TTI2 | c.572T>A p.F191Y | Missense Mutation (SNP) | VAF 82/330 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV62452611; called by muse, mutect2, varscan2
- WDR81 | c.3271G>A p.V1091M (on ENST00000409644 / NM_001163809.2; = p.V40M on NM_152348.4) | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV100489004; called by muse, varscan2
- ZBTB37 | c.275T>C p.I92T | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62932459; called by muse, mutect2, varscan2
- AGBL2 | c.498del p.S168Pfs*51 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | called by mutect2, pindel, varscan2
- IGKV1D-13 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- LMO4 | c.282del p.P95Lfs*7 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- MYO19 | c.490A>G p.I164V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOM1 | c.1380del p.E461Sfs*27 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- PDGFRB | c.269_286del p.L90_G96delinsR | In Frame Del (DEL) | VAF 25/122 reads (20%) | called by mutect2, pindel, varscan2
- SRSF10 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF407 | c.1145_1146dup p.D383* | Frame Shift Ins (INS) | VAF 20/85 reads (24%) | called by mutect2, pindel, varscan2
- ACSM3 | c.298C>T p.L100= | Silent (SNP) | VAF 42/223 reads (19%) | catalogued as COSV55501481; called by muse, mutect2, varscan2
- ADCY9 | c.2628C>T p.P876= | Silent (SNP) | VAF 27/147 reads (18%) | catalogued as rs750255189, COSV53575312; called by muse, mutect2, varscan2
- ASCC3 | c.576A>T p.I192= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV61228547; called by muse, mutect2, varscan2
- DNAH1 | c.12159A>G p.V4053= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV56234490; called by muse, mutect2, varscan2
- FTMT | c.168G>T p.R56= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV58420088, COSV58420379; called by muse, mutect2, varscan2
- IFIT5 | c.471A>G p.Q157= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV65655575; called by muse, mutect2, varscan2
- PLXNB1 | c.3321G>T p.T1107= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV56489687; called by muse, mutect2, varscan2
